Somatic mutation profile of tumor specimen 0DA0VK from CCDI case PBBIMH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.9 years (5,453 days).
Specimen 0DA0VK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 948bc7bb-ee96-4142-bea3-19d097aea291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA0VN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcdbb7d5-f7dc-4856-a927-f4b236529429

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERI2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 26/920 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV55502418; called by muse, mutect2
- ABCA1 | c.4606T>C p.S1536P | Missense Mutation (SNP) | VAF 29/817 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- MIER2 | c.839A>C p.N280T | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, varscan2
- USP15 | c.2430G>A p.P810= (on ENST00000280377 / NM_001351159.2; = p.P781= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 48/400 reads (12%) | catalogued as rs745517169, COSV54795457; called by mutect2, varscan2
- MLIP | c.612+11926C>T | Intron (SNP) | VAF 283/1124 reads (25%) | catalogued as rs767016774; called by muse, mutect2, varscan2
- MTX1 | c.678+94A>G | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
